Gene-level copy-number profile of tumor specimen TCGA-33-4587-01A from TCGA case TCGA-33-4587, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, small cell, nonkeratinizing; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.1 years (23,062 days).
Specimen TCGA-33-4587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f07ccf64-3cc2-40cd-a47d-186f7389ec0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4587-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 832 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50250cf7-28b8-4f29-ae00-c4e0f0017ced

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 165; copy number 2: 9,891; copy number 3: 12,738; copy number 4: 16,806; copy number 5: 11,240; copy number 6: 5,315; copy number 7: 2,009; copy number 8: 1,122; copy number 9: 278; copy number 10: 3; copy number 11: 117; copy number 20: 35; copy number 36: 10; copy number 37: 17; copy number 51: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4587-01A-11D-2121-01): tumor purity 0.88, ploidy 3.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 498 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,795,527–48,472,208, 382 genes, copy number 9–51 (within-gene range 4–51) (broad region; genes not listed).
- chr1:52,554,818–55,215,364, 96 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr1:58,715,609–59,926,773, 17 genes, copy number 9: AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2.
- chr11:97,878,475–98,131,198, 3 genes, copy number 10 (within-gene range 4–10): LINC02713, AP003730.1, AP001317.1.

Autosomal genes at a single copy (total copy number 1): 165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
